Somatic mutation profile of tumor specimen MMRF_1659_1_BM_CD138pos (aliquot MMRF_1659_1_BM_CD138pos_T1_KBS5U_L04819) from MMRF case MMRF_1659, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.0 years (18,618 days).
Specimen MMRF_1659_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30973c47-e708-4015-b7e8-30d097b5ad13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1659_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1659_2_PB_Whole_C1_KBS5U_L04831; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86dbdddd-2f23-40c3-a3db-959f062bb930

The open-access MAF lists 130 somatic variants for this specimen: 59 protein-altering or splice-affecting, 17 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, 3'UTR 34, Silent 17, Intron 12, 3'Flank 3, 5'UTR 3, Nonsense Mutation 2, In Frame Del 2, Frame Shift Ins 1, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1BG | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1280350283, COSV99568395; called by muse, mutect2, varscan2
- ABR | c.856G>A p.D286N (on ENST00000302538 / NM_021962.5; = p.D249N on NM_001092.5) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.349); catalogued as rs766375955; called by muse, mutect2
- CACNA1I | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs1196906789, COSV60807504; called by muse, mutect2, varscan2
- CANX | c.518A>T p.E173V | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as rs775569975; called by muse, mutect2, varscan2
- CNTN3 | c.434G>T p.G145V | Missense Mutation (SNP) | VAF 120/172 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1388559105; called by muse, mutect2, varscan2
- CNTN6 | c.1253dup p.S419Vfs*33 | Frame Shift Ins (INS) | VAF 64/292 reads (22%) | catalogued as rs758676375; called by mutect2, varscan2
- FAM151B | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 104/150 reads (69%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV56474476; called by muse, mutect2, varscan2
- GALNTL6 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs756041431; called by muse, mutect2, varscan2
- HM13 | c.799G>C p.V267L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV59437482; called by muse, mutect2, varscan2
- HNF1B | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374126219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 60/94 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371486752; called by muse, varscan2
- IGHV5-51 | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs566735344; called by muse, mutect2
- IGHV5-51 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 102/229 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs549973566; called by muse, varscan2
- IQCH | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 31/608 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99971954; called by muse, mutect2
- IRAK1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs782207964; called by muse, mutect2, varscan2
- KLK10 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs755105316; called by muse, mutect2, varscan2
- NDUFB1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as rs1302135812; called by muse, mutect2
- NEURL1B | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs1435562072, COSV63940375; called by muse, mutect2, varscan2
- OR13C3 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV101053300, COSV66166122; called by muse, mutect2, varscan2
- RNF113B | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs1167910497, COSV57434659; called by muse, varscan2
- ROBO1 | c.3971C>T p.T1324M | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1045339363, COSV71392720, COSV71397929; called by muse, mutect2, varscan2
- RPS9 | c.-25-8C>T | Splice Region (SNP) | VAF 48/173 reads (28%) | catalogued as COSV100256467; called by muse, mutect2, varscan2
- SPO11 | c.1002G>T p.R334S | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100625710; called by muse, mutect2, varscan2
- TMEM87A | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67747972; called by muse, mutect2
- TRAF3IP3 | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV50551452, COSV50551537; called by muse, mutect2, varscan2
- UNC5A | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149303258; called by muse, varscan2
- USP29 | c.2658del p.I887Ffs*6 | Frame Shift Del (DEL) | VAF 43/241 reads (18%) | catalogued as COSV54146677; called by mutect2, pindel, varscan2
- ZNF18 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs529430089; called by muse, mutect2
- ZNF493 | c.785C>T p.S262L | Missense Mutation (SNP) | VAF 84/380 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100828552, COSV62749591; called by muse, mutect2, varscan2
- ABCC6 | c.1721T>C p.L574P | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ASH1L | c.3877G>A p.E1293K | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- C17orf98 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CCDC152 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CCDC96 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 148/297 reads (50%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.216); called by mutect2, varscan2
- CFHR2 | c.737A>T p.H246L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DTX1 | c.46_60del p.G16_Q20del | In Frame Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- ESRP1 | c.1383C>G p.I461M | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM189A1 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGLV6-57 | c.326A>C p.Y109S | Missense Mutation (SNP) | VAF 154/156 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- KCNH8 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT76 | c.349G>T p.G117* | Nonsense Mutation (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- LEXM | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MOXD1 | c.571A>T p.N191Y | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MRPL54 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- MYEOV | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NETO1 | c.724T>A p.S242T | Missense Mutation (SNP) | VAF 103/456 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PSME1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- SAFB | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 131/471 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SLF1 | c.2626G>T p.V876L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SMAD6 | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 109/476 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK35 | c.953G>A p.C318Y | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNJ2 | c.2569C>T p.P857S | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TACC2 | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by mutect2, varscan2
- TCHH | c.16A>T p.R6* | Nonsense Mutation (SNP) | VAF 59/178 reads (33%) | called by muse, mutect2, varscan2
- TRIM47 | c.83_85del p.F28del | In Frame Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- USPL1 | c.1158G>T p.W386C | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMIZ2 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 72/128 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ZNF157 | c.251A>C p.E84A | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ZNF462 | c.6900C>A p.F2300L | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANK2 | c.7209T>C p.I2403= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- ANKRD18A | c.144G>T p.A48= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- CCR6 | c.612C>T p.V204= | Silent (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- ERVV-2 | c.1110C>T p.L370= | Silent (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- HAS1 | c.1557C>A p.R519= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- HS6ST2 | c.255G>A p.P85= | Silent (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2
- IGHV5-51 | c.60G>A p.E20= | Silent (SNP) | VAF 103/230 reads (45%) | catalogued as rs75660488; called by muse, varscan2
- INAVA | c.1425C>T p.P475= | Silent (SNP) | VAF 123/186 reads (66%) | catalogued as rs201583008, COSV66256355; called by muse, mutect2, varscan2
- LCMT2 | c.147A>G p.A49= | Silent (SNP) | VAF 59/298 reads (20%) | catalogued as COSV59789759; called by muse, mutect2, varscan2
- MEGF6 | c.3432T>C p.T1144= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- OVOL1 | c.453C>T p.C151= | Silent (SNP) | VAF 68/312 reads (22%) | catalogued as rs545994680; called by muse, mutect2, varscan2
- PIEZO2 | c.1158G>A p.R386= | Silent (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
- POU2F3 | c.93G>A p.E31= | Silent (SNP) | VAF 47/212 reads (22%) | catalogued as rs777939631; called by muse, mutect2, varscan2
- QKI | c.63G>A p.L21= | Silent (SNP) | VAF 58/156 reads (37%) | called by muse, varscan2
- TIAM1 | c.4125G>A p.L1375= | Silent (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- TMX3 | c.1347A>G p.L449= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as rs769144543; called by muse, mutect2, varscan2
- ZSCAN29 | c.1944G>A p.E648= | Silent (SNP) | VAF 95/453 reads (21%) | catalogued as rs1163160654; called by muse, mutect2, varscan2
- ABCC4 | c.*748A>G | 3'UTR (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.*1763A>C | 3'UTR (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- AGR2 | c.*399C>T | 3'UTR (SNP) | VAF 91/195 reads (47%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*3942T>A | 3'UTR (SNP) | VAF 54/110 reads (49%) | catalogued as COSV58072376; called by muse, mutect2, varscan2
- BBS1 | c.1339+107G>A | Intron (SNP) | VAF 24/116 reads (21%) | catalogued as rs760183317; called by muse, mutect2, varscan2
- BCAT1 | c.*5564T>C | 3'UTR (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- BLOC1S5 | c.*442G>A | 3'UTR (SNP) | VAF 18/66 reads (27%) | called by muse, mutect2, varscan2
- BTN3A1 | c.*541G>A | 3'UTR (SNP) | VAF 47/180 reads (26%) | called by muse, mutect2, varscan2
- C6orf120 | c.*228T>A | 3'UTR (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- CDK2 | c.-85C>G | 5'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- DCBLD2 | c.*3105_*3115delinsTTGTTTTGTTTTGTT | 3'UTR (INS) | VAF 4/46 reads (9%) | called by pindel, varscan2*
- DIO2 | c.*4389C>G | 3'UTR (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- DNAH10 | c.9645-857C>T | Intron (SNP) | VAF 10/198 reads (5%) | catalogued as rs1278003723; called by muse, mutect2
- EIF2AK3 | c.*512A>G | 3'UTR (SNP) | VAF 38/151 reads (25%) | catalogued as rs1198192467; called by muse, mutect2, varscan2
- EVC | c.1563+1914G>A | Intron (SNP) | VAF 17/47 reads (36%) | called by muse, mutect2, varscan2
- FMNL3 | c.*1361C>A | 3'UTR (SNP) | VAF 6/154 reads (4%) | called by muse, mutect2
- FOXI1 | c.*181C>A | 3'UTR (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- FOXL1 | c.*1365_*1379del | 3'UTR (DEL) | VAF 29/79 reads (37%) | called by mutect2, pindel, varscan2
- GABRB3 | c.241-20933C>T | Intron (SNP) | VAF 44/191 reads (23%) | called by muse, mutect2, varscan2
- GAPVD1 | c.3047-210A>C | Intron (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- HMGA2 | c.282+2158A>T | Intron (SNP) | VAF 70/155 reads (45%) | called by muse, mutect2, varscan2
- HSF4 | c.1255-80G>T | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs530911272; called by muse, mutect2, varscan2
- IFT80 | c.*317T>C | 3'UTR (SNP) | VAF 61/237 reads (26%) | called by muse, mutect2, varscan2
- IRF9 | c.*151G>T | 3'UTR (SNP) | VAF 98/273 reads (36%) | called by muse, mutect2, varscan2
- IZUMO3 | chr9:24545935 C>A | 5'Flank (SNP) | VAF 12/53 reads (23%) | called by muse, mutect2
- KAZN | c.*1559C>T | 3'UTR (SNP) | VAF 10/166 reads (6%) | called by muse, mutect2
- KIF21B | chr1:200970213 T>A | 3'Flank (SNP) | VAF 54/237 reads (23%) | called by muse, mutect2, varscan2
- KRTAP2-1 | c.*74G>A | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, mutect2, varscan2
- LILRA1 | c.*585G>T | 3'UTR (SNP) | VAF 53/298 reads (18%) | catalogued as rs189371015; called by muse, mutect2, varscan2
- LRRC28 | c.*1312G>A | 3'UTR (SNP) | VAF 76/274 reads (28%) | catalogued as rs771171841, COSV57343172; called by muse, mutect2, varscan2
- MBL2 | c.*1892C>T | 3'UTR (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- MLLT3 | c.*3398A>G | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- MLPH | c.*553C>A | 3'UTR (SNP) | VAF 57/114 reads (50%) | called by muse, mutect2, varscan2
- MUC21 | c.*250C>T | 3'UTR (SNP) | VAF 28/118 reads (24%) | catalogued as rs760272681; called by muse, mutect2, varscan2
- MXD3 | chr5:177305703 C>G | 3'Flank (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- NDN | c.*527G>A | 3'UTR (SNP) | VAF 42/260 reads (16%) | catalogued as rs997240609; called by muse, mutect2, varscan2
- NMRK1 | c.*2G>A | 3'UTR (SNP) | VAF 109/396 reads (28%) | catalogued as COSV100738049; called by muse, mutect2, varscan2
- NRXN1 | c.-685T>A | 5'UTR (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- NSD3 | c.1856-1345T>C | Intron (SNP) | VAF 39/70 reads (56%) | called by muse, mutect2, varscan2
- NSL1 | c.*11353C>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | catalogued as rs371938400; called by muse, mutect2, varscan2
- RPL18A | c.329-81C>T | Intron (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- SESN3 | c.*5786del | 3'UTR (DEL) | VAF 59/246 reads (24%) | catalogued as rs909803134; called by mutect2, pindel, varscan2
- SMG1 | c.*4455G>A | 3'UTR (SNP) | VAF 47/136 reads (35%) | called by muse, mutect2, varscan2
- SMG5 | c.*1082G>A | 3'UTR (SNP) | VAF 54/138 reads (39%) | called by muse, mutect2, varscan2
- SOWAHA | c.*578T>C | 3'UTR (SNP) | VAF 28/130 reads (22%) | called by muse, mutect2, varscan2
- SPTLC1 | c.-31T>C | 5'UTR (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- TH | c.406-18C>A | Intron (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- UBASH3B | c.*323A>C | 3'UTR (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- VEGFA | c.546-85T>A | Intron (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- VEZT | c.*431_*434del | 3'UTR (DEL) | VAF 22/56 reads (39%) | called by pindel, varscan2
- WTAP | chr6:159761070 ins T | 3'Flank (INS) | VAF 40/78 reads (51%) | called by mutect2, pindel, varscan2
- ZFPM2 | n.274G>T | RNA (SNP) | VAF 45/116 reads (39%) | called by muse, mutect2, varscan2
- ZNF254 | c.253+629T>C | Intron (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- ZNF516 | c.*1389T>A | 3'UTR (SNP) | VAF 93/186 reads (50%) | catalogued as COSV71587697; called by muse, mutect2, varscan2
